Somatic mutation profile of tumor specimen TARGET-10-PAPBLU-09A (aliquot TARGET-10-PAPBLU-09A-01D) from TARGET case TARGET-10-PAPBLU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,877 days).
Specimen TARGET-10-PAPBLU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 584483a6-ebf5-40c1-88f2-f5d722b0cf6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPBLU-10A (Blood Derived Normal), aliquot TARGET-10-PAPBLU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47e2a29b-8a0b-48c6-9eb2-56e0badfec62

The open-access MAF lists 18 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 4, Silent 3, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACHE | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.441); catalogued as rs1030385619, COSV53822038; called by muse, mutect2, varscan2
- ALK | c.4378G>C p.E1460Q | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.167); catalogued as COSV66580234; called by muse, mutect2
- DST | c.21025C>T p.R7009* (on ENST00000361203 / NM_001374722.1; = p.R4706* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99750239; called by muse, mutect2, varscan2
- NAA35 | c.1639G>C p.E547Q | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV64484811; called by muse, mutect2
- TNC | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs752072781; called by muse, mutect2, varscan2
- ZFYVE19 | c.994C>T p.R332* (on ENST00000355341 / NM_001077268.2; = p.R322* on NM_032850.5) | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | catalogued as rs376725467; called by muse, mutect2, varscan2
- SAE1 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, varscan2
- SLC16A12 | c.93G>T p.M31I | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.437); called by muse, mutect2
- ZBED6 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- ZC3H15 | c.827G>A p.R276K | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADRA1A | c.1386C>T p.N462= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs201746874; called by muse, mutect2, varscan2
- BICRA | c.3168G>A p.G1056= | Silent (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- KIAA0319 | c.219C>T p.F73= | Silent (SNP) | VAF 45/89 reads (51%) | catalogued as rs560298185, COSV65496456; called by muse, mutect2, varscan2
- AC008687.1 | c.-184C>T | 5'UTR (SNP) | VAF 31/120 reads (26%) | catalogued as rs759076930; called by muse, mutect2, varscan2
- AGBL4 | c.34+28445C>T | Intron (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- CCBE1 | c.212+102G>A | Intron (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- ICAM3 | c.1192+53A>T | Intron (SNP) | VAF 45/131 reads (34%) | called by muse, mutect2, varscan2
- ZBTB37 | c.1023+76_1023+87delinsCCC | Intron (DEL) | VAF 16/47 reads (34%) | called by pindel, varscan2*
